Gene-level copy-number profile of tumor specimen TCGA-BA-7269-01A from TCGA case TCGA-BA-7269, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 61.9 years (22,609 days).
Specimen TCGA-BA-7269-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.4645e0ba-1151-413b-8f04-4d69d789b9be.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-7269-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3b6158fd-c1e2-4e9a-84a6-0c39a549edee

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 93; copy number 1: 4,005; copy number 2: 19,496; copy number 3: 19,479; copy number 4: 9,820; copy number 5: 1,443; copy number 6: 3,213; copy number 7: 199; copy number 8: 1,136; copy number 9: 301; copy number 10: 41; copy number 11: 54; copy number 12: 115; copy number 13: 2; copy number 14: 10; copy number 15: 68; copy number 16: 10; copy number 17: 59; copy number 20: 29; copy number 22: 194; copy number 25: 45; copy number 26: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-7269-01A-11D-2010-01): tumor purity 0.55, ploidy 3.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 93 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:34,109,560–34,815,325, 3 genes (within-gene range 0–2): PARD3, Y_RNA, ELOBP4.
- chr11:103,109,410–105,531,697, 33 genes (within-gene range 0–6): DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1, AP003304.1, LINC02552, AP001485.1, AP002004.1, CASP12, CASP4LP, CASP4, AP001153.1, CASP5, CASP1, CARD16, AP001153.2, CASP1P2, CARD17, CASP1P1, CARD18, OR2AL1P, AP003181.1, Metazoa_SRP.
- chr11:109,637,468–112,022,653, 56 genes (within-gene range 0–2): AP003102.1, LINC02715, RDX, TFAMP2, AP001981.2, RPSAP50, AP001981.1, AP001889.1, ZC3H12C, LINC02732, FDX1, ARHGAP20, HNRNPA1P60, AP002963.1, AP003973.4, RNA5SP350, AP003973.2, LINC02550, AP003973.3, RPS17P15, AP003973.1, C11orf53, COLCA1, COLCA2, AP002448.1, MIR4491, POU2AF1, RNU2-60P, AP002008.3, AP002008.2, BTG4, AP002008.4, MIR34B, MIR34C, AP002008.1, HOATZ, LAYN, SIK2, AP000925.1, RN7SKP273, PPP2R1B, AP001781.1, ALG9, AP001781.2, ALG9-IT1, GNG5P3, FDXACB1, C11orf1, RPL37AP8, CRYAB, HSPB2, HSPB2-C11orf52, C11orf52, DIXDC1, RNA5SP351, AP000907.1.
- chr11:135,061,781–135,075,908, 1 gene: LINC02684.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,266 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,235,806–151,459,494, 211 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr1:183,248,237–186,988,981, 69 genes, copy number 8–9 (broad region; genes not listed).
- chr2:48,217,575–48,515,391, 6 genes, copy number 10: RN7SKP224, FOXN2, RNU4-49P, AC093635.1, PPP1R21, RNU6-282P.
- chr2:73,700,576–73,824,593, 7 genes, copy number 10: NAT8B, TPRKB, AC092653.1, AC092653.2, DUSP11, C2orf78, AC073046.4.
- chr2:73,834,422–73,856,965, 1 gene, copy number 10 (within-gene range 3–10): AC073046.3.
- chr2:81,418,723–81,496,327, 3 genes, copy number 11: CHMP4AP1, LINC01815, RNA5SP99.
- chr4:123,861,860–125,492,932, 11 genes, copy number 9 (within-gene range 4–9): AC093767.1, AC108075.1, PPIAP76, AC121154.1, AC133530.1, TUBAP10, TECRP2, LINC02516, ANKRD50, FAT4, Y_RNA.
- chr5:58,198–45,895,970, 710 genes, copy number 8 (broad region; genes not listed).
- chr7:45,888,360–56,000,181, 138 genes, copy number 22 (broad region; genes not listed).
- chr7:133,732,493–134,579,875, 9 genes, copy number 7: RPS3AP27, LRGUK, AC008154.2, SLC35B4, AC008154.1, AC009275.1, AKR1B1, AKR1B10, AKR1B15.
- chr8:19,313,693–20,700,152, 17 genes, copy number 10: SH2D4A, AC068880.4, CSGALNACT1, AC090541.1, INTS10, LPL, AC100802.1, RPL30P9, SLC18A1, ATP6V1B2, RNU6-892P, LZTS1, LZTS1-AS1, RNA5SP257, AC023403.1, AC022559.1, AC018541.1.
- chr8:37,326,575–38,704,855, 54 genes, copy number 9: AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1.
- chr8:46,028,804–49,907,446, 71 genes, copy number 8 (broad region; genes not listed).
- chr8:67,952,046–81,533,275, 211 genes, copy number 7–17 (within-gene range 6–17) (broad region; genes not listed).
- chr8:84,665,759–92,144,435, 107 genes, copy number 7–9 (broad region; genes not listed).
- chr8:104,590,733–131,432,869, 307 genes, copy number 8–12 (within-gene range 6–12) (broad region; genes not listed).
- chr11:58,242,043–58,578,220, 17 genes, copy number 7: EIF4A2P3, OR10W1, OR10Q2P, OR5BC1P, OR5B19P, OR5B10P, AP000435.1, OR5B17, OR5B1P, OR5B15P, OR5B3, OR5B2, OR5B12, AP003557.2, AP003557.1, OR5B21, LPXN.
- chr11:62,989,154–63,144,221, 5 genes, copy number 7: SLC22A8, AP001858.1, TUBAP7, SLC22A24, RPL29P22.
- chr11:69,294,151–70,436,584, 36 genes, copy number 25: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,647,562, 4 genes, copy number 25: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2.
- chr11:77,313,606–78,444,049, 36 genes, copy number 9: TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728.
- chr11:83,455,012–85,627,922, 1 gene, copy number 14 (within-gene range 1–25): DLG2.
- chr11:84,545,131–85,682,908, 14 genes, copy number 14–25 (within-gene range 2–25): HNRNPA1P72, AP000852.1, AP001825.1, AP001825.2, AP001825.3, AP000857.2, AP000857.1, HNRNPCP6, AP002803.1, AP003035.1, RNU6-1292P, TMEM126B, TMEM126A, CREBZF.
- chr11:89,498,748–90,915,052, 59 genes, copy number 9–22 (within-gene range 2–22): H3P34, AP003400.4, AP003400.5, AP003400.1, AP003400.2, AP003400.3, AP003400.6, FOLH1B, UBTFL10, AP003122.6, TRIM77, AP003122.4, AP003122.5, UBTFL2, AP003122.2, AP003122.3, AP003122.1, TRIM64DP, AP004833.2, AP004833.3, TRIM49, AP004833.1, TRIM53BP, TRIM51BP, AP005435.1, TRIM64B, AP005435.4, AP005435.2, AP005435.3, MTND1P35, TRIM49D1, TRIM49D2, AP004607.3, AP004607.9, AP004607.8, AP004607.1, TRIM64, AP004607.7, TRIM51EP, TRIM53AP, AP004607.6, TRIM49C, AP004607.2, AP004607.4, TRIM64EP, AP004607.5, AP000827.1, UBTFL1, AP000648.2, AP000648.9, AP000648.1, AP000648.3, NAALAD2, AP000648.4, CHORDC1, AP002364.1, DISC1FP1, TUBAP2, MIR4490.
- chr11:118,133,377–118,679,690, 29 genes, copy number 20: SCN4B, SCN2B, JAML, HSPE1P18, MPZL3, MPZL2, AP002800.1, CD3E, AP001582.1, CD3D, CD3G, UBE4A, AP001267.1, AP001267.5, ATP5MG, AP001267.4, AP001267.2, KMT2A, AP001267.3, TTC36, TMEM25, IFT46, RPL5P30, ARCN1, RNU6-1157P, PHLDB1, AP000941.1, MIR6716, TREH.
- chr11:120,511,746–120,988,906, 1 gene, copy number 26 (within-gene range 2–26): GRIK4.
- chr11:120,867,933–120,936,654, 2 genes, copy number 26: AP004147.1, HMGB1P42.
- chr12:65,050,626–68,332,381, 61 genes, copy number 11–16 (within-gene range 2–16) (broad region; genes not listed).
- chr19:14,514,769–14,917,380, 23 genes, copy number 7: DNAJB1, TECR, MIR639, NDUFB7, CLEC17A, RN7SL337P, RN7SL842P, ADGRE3, ITGB1P1, AC022149.1, ZNF333, ADGRE2, OR7C1, AC005255.1, OR7A5, OR7A10, OR7A8P, OR7A2P, OR7A17, OR7A18P, OR7A1P, OR7A3P, OR7A11P.
- chr19:15,221,015–15,898,077, 38 genes, copy number 7 (within-gene range 3–7): AC004257.1, EPHX3, BRD4, AC005776.1, AC005776.2, AKAP8, AC005785.1, AKAP8L, AC005785.2, AC006128.1, WIZ, MIR1470, RASAL3, PGLYRP2, CYP4F22, AC011492.1, CYP4F23P, AD000091.1, RPL23AP2, AC093072.1, CYP4F8, CYP4F3, CYP4F10P, CYP4F12, OR10H2, OR10H3, CYP4F24P, AC004597.1, OR10H5, OR10H1, ZNF861P, AC004510.2, LINC01764, UCA1, AC004510.1, CLEC4O, CYP4F36P, CYP4F2.
- chr19:16,161,368–16,245,906, 6 genes, copy number 7 (within-gene range 3–7): CIB3, FAM32A, AC020911.1, Metazoa_SRP, AC020911.3, AP1M1.
- chr22:42,835,412–43,015,149, 2 genes, copy number 10 (within-gene range 6–10): PACSIN2, AL049758.1.

Autosomal genes at a single copy (total copy number 1): 3,166. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
